Somatic mutation profile of tumor specimen TCGA-IG-A8O2-01A (aliquot TCGA-IG-A8O2-01A-11D-A36J-09) from TCGA case TCGA-IG-A8O2, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower third of esophagus; AJCC pathologic stage: Stage IIIB; Tumor grade: G3; Age at diagnosis: 62.6 years (22,869 days).
Specimen TCGA-IG-A8O2-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a4454fe2-c206-47f5-920a-d1a095b63def.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-IG-A8O2-10A (Blood Derived Normal), aliquot TCGA-IG-A8O2-10A-01D-A36M-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ea06048d-0d59-4200-8599-4b4c7a0aa053

The open-access MAF lists 141 somatic variants for this specimen: 104 protein-altering or splice-affecting, 33 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 89, Silent 33, Nonsense Mutation 7, Frame Shift Del 4, Splice Site 2, Intron 2, In Frame Del 1, Frame Shift Ins 1, 5'UTR 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CHRNA1 | c.1072C>T p.R358W (on ENST00000261007 / NM_001039523.3; = p.R333W on NM_000079.4) | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs374391312, CM086805; ClinVar: uncertain significance / pathogenic; called by muse, mutect2, varscan2
- NFE2L2 | c.235G>A p.E79K | Missense Mutation (SNP) | VAF 50/135 reads (37%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1057519922, COSV67959999, COSV67960008, COSV67960140; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.503A>G p.H168R | Missense Mutation (SNP) | VAF 17/28 reads (61%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as rs867114783, COSV52676197, COSV52682212, COSV52698349, COSV52762255; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ADGRL2 | c.886C>G p.L296V | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99592072; called by muse, mutect2, varscan2
- AGPS | c.1084C>T p.H362Y | Missense Mutation (SNP) | VAF 66/182 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as COSV51565615; called by muse, mutect2, varscan2
- ARR3 | c.518C>T p.P173L | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs766517164, COSV52103608; called by muse, mutect2, varscan2
- BNIP3 | c.616G>A p.A206T | Missense Mutation (SNP) | VAF 26/92 reads (28%) | SIFT tolerated (0.19); PolyPhen benign (0.044); catalogued as rs1451737717, COSV64043886; called by muse, mutect2, varscan2
- C19orf54 | c.742G>A p.V248M | Missense Mutation (SNP) | VAF 3/29 reads (10%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.864); catalogued as rs1425540459; called by muse, mutect2
- CACNA2D4 | c.2188G>A p.A730T | Missense Mutation (SNP) | VAF 30/66 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.802); catalogued as rs368331985; called by muse, mutect2, varscan2
- CCDC85A | c.1336C>T p.Q446* | Nonsense Mutation (SNP) | VAF 46/122 reads (38%) | catalogued as rs1489451247; called by muse, mutect2, varscan2
- CHD7 | c.4607A>G p.K1536R | Missense Mutation (SNP) | VAF 18/137 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.341); catalogued as COSV71107701; called by muse, varscan2
- ETNPPL | c.541G>C p.D181H | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); catalogued as rs772650876, COSV56595837; called by muse, mutect2, varscan2
- FAT1 | c.6685A>G p.I2229V | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT tolerated (0.09); PolyPhen benign (0.036); catalogued as rs759239082; called by muse, mutect2, varscan2
- GCM2 | c.199C>T p.R67C | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs532834782, COSV65276478; called by muse, mutect2, varscan2
- GLB1L | c.1215G>C p.E405D | Missense Mutation (SNP) | VAF 41/105 reads (39%) | SIFT deleterious (0.05); PolyPhen benign (0.289); catalogued as rs1357828979; called by muse, mutect2, varscan2
- HNRNPDL | c.1178A>T p.Y393F | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT tolerated, low confidence (0.19); PolyPhen possibly damaging (0.899); catalogued as COSV99787028; called by muse, mutect2, varscan2
- HTR1F | c.61C>G p.P21A | Missense Mutation (SNP) | VAF 20/142 reads (14%) | SIFT tolerated (0.86); PolyPhen benign (0.036); catalogued as COSV60390267; called by muse, mutect2, varscan2
- IGFBP3 | c.455C>T p.P152L | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT tolerated (0.35); PolyPhen benign (0.001); catalogued as rs1444186739, COSV51873329; called by muse, mutect2, varscan2
- KRR1 | c.761G>T p.R254L | Missense Mutation (SNP) | VAF 35/106 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.366); catalogued as COSV99875458; called by muse, mutect2, varscan2
- LCT | c.4330G>A p.V1444M | Missense Mutation (SNP) | VAF 23/113 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as rs757039689, COSV99930157; called by muse, mutect2, varscan2
- LDHD | c.1114A>G p.N372D | Missense Mutation (SNP) | VAF 24/49 reads (49%) | SIFT tolerated (0.76); PolyPhen benign (0.023); catalogued as rs752556264; called by muse, mutect2, varscan2
- LRRC4 | c.1657C>T p.R553W | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs1159200016, COSV50814223; called by muse, mutect2, varscan2
- MEGF10 | c.1130G>A p.S377N | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV99175156; called by muse, mutect2, varscan2
- MSH2 | c.1810G>A p.A604T | Missense Mutation (SNP) | VAF 38/110 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.796); catalogued as rs1553368568; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- OR2T11 | c.239C>A p.A80E | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.017); catalogued as rs200166974, COSV58186721; called by muse, mutect2, varscan2
- OR2T33 | c.179T>G p.L60R | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs544654849, COSV58815741; called by muse, mutect2, varscan2
- P2RX3 | c.674C>T p.A225V | Missense Mutation (SNP) | VAF 99/173 reads (57%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.852); catalogued as rs867187062, COSV54443874; called by muse, mutect2, varscan2
- PHC2 | c.1967G>A p.R656H (on ENST00000257118 / NM_198040.2; = p.R121H on NM_004427.4) | Missense Mutation (SNP) | VAF 24/89 reads (27%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.854); catalogued as rs1324338884, COSV57101652; called by muse, mutect2, varscan2
- PIGT | c.237G>T p.K79N | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.855); catalogued as COSV54124959; called by muse, mutect2, varscan2
- PJVK | c.509C>T p.S170L | Missense Mutation (SNP) | VAF 41/99 reads (41%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.811); catalogued as CD073602; called by muse, mutect2, varscan2
- PLEKHM3 | c.707C>T p.S236L | Missense Mutation (SNP) | VAF 18/101 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); catalogued as COSV101216557; called by muse, mutect2, varscan2
- SARM1 | c.719C>A p.A240E | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as rs1449836804; called by muse, mutect2
- SCAF11 | c.3613A>G p.I1205V | Missense Mutation (SNP) | VAF 26/141 reads (18%) | SIFT tolerated (0.94); PolyPhen benign (0); catalogued as rs150376258; called by muse, mutect2, varscan2
- SLX4 | c.679G>A p.A227T | Missense Mutation (SNP) | VAF 25/51 reads (49%) | SIFT tolerated (0.48); PolyPhen benign (0.001); catalogued as rs147872182; called by muse, mutect2, varscan2
- SOCS6 | c.511G>A p.V171I | Missense Mutation (SNP) | VAF 25/54 reads (46%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.019); catalogued as rs755164587; called by muse, mutect2, varscan2
- STARD5 | c.241G>A p.E81K | Missense Mutation (SNP) | VAF 27/41 reads (66%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV57155758; called by muse, mutect2, varscan2
- TMEM159 | c.250G>A p.V84I | Missense Mutation (SNP) | VAF 21/90 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.629); catalogued as COSV51785286; called by muse, mutect2, varscan2
- XKR4 | c.380G>A p.G127D | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.575); catalogued as COSV100532677; called by muse, mutect2
- ZFP90 | c.1781C>A p.T594N | Missense Mutation (SNP) | VAF 25/92 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.027); catalogued as rs375588905, COSV68050923; called by muse, mutect2, varscan2
- ZIC1 | c.1063G>C p.V355L | Missense Mutation (SNP) | VAF 18/118 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.033); catalogued as rs1318829754, COSV51551901; called by muse, mutect2, varscan2
- ZNF33A | c.2215C>T p.Q739* (on ENST00000458705 / NM_006974.3; = p.Q740* on NM_006954.2) | Nonsense Mutation (SNP) | VAF 19/120 reads (16%) | catalogued as rs267602486, COSV56725804, COSV56727361; called by muse, mutect2, varscan2
- AC131160.1 | c.895_906delinsT p.I299Yfs*29 | Frame Shift Del (DEL) | VAF 24/103 reads (23%) | called by pindel, varscan2*
- ADAM2 | c.269A>T p.N90I | Missense Mutation (SNP) | VAF 54/128 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.179); called by muse, mutect2, varscan2
- AQP12A | c.284C>T p.S95F | Missense Mutation (SNP) | VAF 24/108 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- ATRNL1 | c.3778G>A p.A1260T | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.257); called by muse, mutect2, varscan2
- B3GAT2 | c.758T>A p.V253D | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- BNC2 | c.1412G>T p.C471F | Missense Mutation (SNP) | VAF 9/88 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- C1orf105 | c.107+2T>C p.X36_splice | Splice Site (SNP) | VAF 13/56 reads (23%) | called by muse, mutect2, varscan2
- C2orf73 | c.167A>G p.N56S | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT tolerated (0.17); PolyPhen benign (0.116); called by muse, mutect2, varscan2
- CADM2 | c.643C>G p.Q215E (on ENST00000407528 / NM_001167674.2; = p.Q217E on NM_153184.4) | Missense Mutation (SNP) | VAF 10/134 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.007); called by muse, mutect2
- CAPN7 | c.36G>T p.Q12H | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT tolerated (0.17); PolyPhen benign (0); called by muse, mutect2, varscan2
- CCDC15 | c.2357G>C p.R786T | Missense Mutation (SNP) | VAF 24/110 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CCDC17 | c.671C>T p.S224F | Missense Mutation (SNP) | VAF 79/167 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.461); called by muse, mutect2, varscan2
- CFH | c.1749G>C p.K583N | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.072); called by muse, mutect2, varscan2
- CHD7 | c.4606A>C p.K1536Q | Missense Mutation (SNP) | VAF 18/136 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.641); called by muse, varscan2
- CMTM2 | c.267G>C p.E89D | Missense Mutation (SNP) | VAF 26/70 reads (37%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.647); called by muse, mutect2, varscan2
- COX5A | c.239A>G p.Y80C | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- CRISPLD1 | c.1207C>G p.L403V | Missense Mutation (SNP) | VAF 35/83 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.334); called by muse, mutect2, varscan2
- EPAS1 | c.1699dup p.M567Nfs*44 | Frame Shift Ins (INS) | VAF 21/60 reads (35%) | called by mutect2, pindel, varscan2
- EPRS1 | c.2920A>T p.K974* | Nonsense Mutation (SNP) | VAF 37/74 reads (50%) | called by muse, mutect2, varscan2
- EXOC7 | c.306A>C p.R102S | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- FBXO15 | c.483del p.K161Nfs*3 | Frame Shift Del (DEL) | VAF 7/59 reads (12%) | called by mutect2, pindel, varscan2
- FXR1 | c.1474G>A p.D492N | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.977); called by muse, mutect2
- GABRG3 | c.1384G>A p.V462I | Missense Mutation (SNP) | VAF 20/146 reads (14%) | SIFT tolerated (0.43); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- GSG1L | c.820T>G p.F274V (on ENST00000447459 / NM_001109763.2; = p.F119V on NM_144675.2) | Missense Mutation (SNP) | VAF 36/64 reads (56%) | SIFT tolerated (0.12); PolyPhen benign (0.219); called by muse, mutect2, varscan2
- HYDIN | c.8242G>A p.A2748T | Missense Mutation (SNP) | VAF 28/115 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.392); called by muse, mutect2, varscan2
- ITGAM | c.2969C>T p.T990I (on ENST00000648685 / NM_001145808.2; = p.T989I on NM_000632.4) | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.75); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- KLK9 | c.729G>C p.W243C | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KLRF1 | c.494T>G p.L165R | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- LARP4B | c.1247C>T p.S416F | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.825); called by muse, mutect2, varscan2
- LRRC41 | c.248A>G p.Y83C | Missense Mutation (SNP) | VAF 54/132 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- LRRK2 | c.6900G>T p.L2300F | Missense Mutation (SNP) | VAF 16/114 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- MAN2A2 | c.2927T>C p.L976P | Missense Mutation (SNP) | VAF 66/110 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- MEP1B | c.379T>C p.S127P | Missense Mutation (SNP) | VAF 20/117 reads (17%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.912); called by muse, mutect2, varscan2
- MRPS22 | c.975T>A p.N325K (on ENST00000310776 / NM_001363893.1; = p.N326K on NM_020191.4) | Missense Mutation (SNP) | VAF 33/168 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NIPA2 | c.716C>T p.A239V | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- NOTCH3 | c.3750_3763del p.C1250Wfs*10 | Frame Shift Del (DEL) | VAF 19/107 reads (18%) | called by mutect2, pindel, varscan2
- ODF2L | c.457G>A p.E153K | Missense Mutation (SNP) | VAF 13/105 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- OPA3 | c.529G>A p.A177T | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT tolerated, low confidence (0.63); PolyPhen benign (0); called by muse, mutect2, varscan2
- OPRL1 | c.1061A>G p.K354R | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR2B2 | c.805G>T p.D269Y | Missense Mutation (SNP) | VAF 13/97 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- PDE3A | c.1425-2A>C p.X475_splice | Splice Site (SNP) | VAF 16/75 reads (21%) | called by muse, mutect2, varscan2
- RTN1 | c.1636G>T p.E546* | Nonsense Mutation (SNP) | VAF 25/68 reads (37%) | called by muse, mutect2, varscan2
- SEMA6D | c.2173G>T p.V725F (on ENST00000316364 / NM_153618.2; = p.V663F on NM_020858.2) | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SIN3B | c.2122G>A p.A708T | Missense Mutation (SNP) | VAF 24/102 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0.048); called by muse, varscan2
- SLC3A1 | c.791G>C p.W264S | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- SLC3A1 | c.796_801del p.F266_D267del | In Frame Del (DEL) | VAF 10/80 reads (13%) | called by mutect2, pindel
- SLC8A1 | c.761G>T p.R254M | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- SLCO1C1 | c.830G>C p.G277A | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SRPRA | c.310_313del p.L104Vfs*3 | Frame Shift Del (DEL) | VAF 12/42 reads (29%) | called by mutect2, pindel, varscan2
- ST14 | c.1526A>T p.D509V | Missense Mutation (SNP) | VAF 27/58 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- STIL | c.1365G>T p.L455F | Missense Mutation (SNP) | VAF 29/88 reads (33%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.885); called by muse, mutect2, varscan2
- SYNE2 | c.5785T>C p.S1929P | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.855); called by muse, mutect2, varscan2
- TADA1 | c.370C>T p.Q124* | Nonsense Mutation (SNP) | VAF 12/74 reads (16%) | called by muse, mutect2, varscan2
- TAF7 | c.700G>T p.D234Y | Missense Mutation (SNP) | VAF 15/25 reads (60%) | SIFT deleterious (0); PolyPhen possibly damaging (0.556); called by muse, mutect2, varscan2
- TBC1D25 | c.634G>A p.G212S | Missense Mutation (SNP) | VAF 14/17 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TENM1 | c.2612G>A p.S871N | Missense Mutation (SNP) | VAF 21/23 reads (91%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.849); called by muse, mutect2, varscan2
- TRPC1 | c.1634T>G p.L545R (on ENST00000476941 / NM_001251845.2; = p.L511R on NM_003304.4) | Missense Mutation (SNP) | VAF 29/188 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- TTN | c.90125G>T p.S30042I (on ENST00000591111; = p.S22618I on NM_003319.4) | Missense Mutation (SNP) | VAF 29/76 reads (38%) | PolyPhen possibly damaging (0.775); called by muse, mutect2, varscan2
- UFC1 | c.103G>T p.E35* | Nonsense Mutation (SNP) | VAF 60/99 reads (61%) | called by muse, mutect2, varscan2
- VPS13B | c.2636G>T p.C879F | Missense Mutation (SNP) | VAF 37/158 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.319); called by muse, mutect2, varscan2
- WDR41 | c.845A>G p.N282S | Missense Mutation (SNP) | VAF 27/48 reads (56%) | SIFT tolerated (0.54); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZNF557 | c.989A>T p.Q330L (on ENST00000414706 / NM_001044388.2; = p.Q337L on NM_024341.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/85 reads (19%) | SIFT tolerated (0.71); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- ZNF750 | c.164T>G p.L55* | Nonsense Mutation (SNP) | VAF 51/72 reads (71%) | called by muse, mutect2, varscan2
- ABCA6 | c.1971G>A p.L657= | Silent (SNP) | VAF 53/71 reads (75%) | called by muse, mutect2, varscan2
- ARFGEF2 | c.5253C>T p.L1751= | Silent (SNP) | VAF 19/114 reads (17%) | catalogued as rs1309682966; called by muse, mutect2, varscan2
- ARHGAP10 | c.585G>A p.E195= | Silent (SNP) | VAF 30/84 reads (36%) | catalogued as COSV60607585; called by muse, mutect2, varscan2
- ARID1A | c.4641C>T p.S1547= | Silent (SNP) | VAF 45/97 reads (46%) | catalogued as rs1308726726; called by muse, mutect2, varscan2
- CALCR | c.69T>A p.L23= | Silent (SNP) | VAF 9/21 reads (43%) | called by muse, mutect2, varscan2
- CCDC81 | c.1209G>A p.P403= (on ENST00000445632 / NM_001156474.2; = p.P313= on NM_021827.4) | Silent (SNP) | VAF 41/185 reads (22%) | catalogued as rs553491893; called by muse, mutect2, varscan2
- CHD7 | c.4605T>G p.A1535= | Silent (SNP) | VAF 18/136 reads (13%) | called by muse, varscan2
- CIZ1 | c.2571A>C p.T857= | Silent (SNP) | VAF 29/86 reads (34%) | called by muse, mutect2, varscan2
- CNEP1R1 | c.153A>T p.I51= (on ENST00000427478 / NM_001281789.1; = p.I68= on NM_153261.5) | Silent (SNP) | VAF 21/118 reads (18%) | called by muse, mutect2, varscan2
- DLC1 | c.4281C>T p.Y1427= (on ENST00000276297 / NM_001348081.2; = p.Y990= on NM_006094.5) | Silent (SNP) | VAF 12/88 reads (14%) | catalogued as rs73552359; called by muse, mutect2, varscan2
- DPP9 | c.1554C>G p.T518= (on ENST00000598800; = p.T547= on NM_139159.5) | Silent (SNP) | VAF 14/26 reads (54%) | called by muse, mutect2, varscan2
- FHOD1 | c.1548G>A p.K516= | Silent (SNP) | VAF 19/110 reads (17%) | called by muse, mutect2, varscan2
- GOLPH3 | c.633G>A p.Q211= | Silent (SNP) | VAF 23/114 reads (20%) | catalogued as COSV54062240; called by muse, mutect2, varscan2
- HOXD10 | c.624G>A p.Q208= | Silent (SNP) | VAF 42/111 reads (38%) | called by muse, mutect2, varscan2
- HSD17B12 | c.555G>A p.L185= | Silent (SNP) | VAF 16/62 reads (26%) | catalogued as COSV53501673; called by muse, mutect2, varscan2
- INCENP | c.832C>A p.R278= | Silent (SNP) | VAF 24/79 reads (30%) | called by muse, mutect2, varscan2
- KIAA0319 | c.2397G>A p.S799= | Silent (SNP) | VAF 37/91 reads (41%) | catalogued as rs571054596, COSV65500695; called by muse, mutect2, varscan2
- KIF3C | c.1071C>G p.R357= | Silent (SNP) | VAF 8/126 reads (6%) | called by muse, mutect2
- LINGO1 | c.1158G>C p.R386= | Silent (SNP) | VAF 17/58 reads (29%) | called by muse, mutect2, varscan2
- LRFN2 | c.1209C>T p.S403= | Silent (SNP) | VAF 16/84 reads (19%) | catalogued as COSV57836507; called by muse, mutect2, varscan2
- MAP3K4 | c.2064C>T p.D688= | Silent (SNP) | VAF 5/42 reads (12%) | catalogued as rs374997561; called by mutect2, varscan2
- OR4C11 | c.252C>T p.L84= | Silent (SNP) | VAF 49/64 reads (77%) | catalogued as rs767460262; called by muse, mutect2, varscan2
- PEX2 | c.165G>A p.E55= | Silent (SNP) | VAF 18/109 reads (17%) | called by muse, mutect2, varscan2
- PIK3AP1 | c.285G>A p.P95= | Silent (SNP) | VAF 10/53 reads (19%) | called by muse, mutect2, varscan2
- POMP | c.213G>A p.Q71= | Silent (SNP) | VAF 10/53 reads (19%) | called by muse, mutect2, varscan2
- PRAM1 | c.1944G>A p.E648= | Silent (SNP) | VAF 14/46 reads (30%) | called by muse, mutect2, varscan2
- PURG | c.450G>A p.Q150= | Silent (SNP) | VAF 9/30 reads (30%) | called by muse, mutect2, varscan2
- ROBO4 | c.1872C>T p.L624= | Silent (SNP) | VAF 40/81 reads (49%) | called by muse, mutect2, varscan2
- SGTA | c.594C>T p.N198= | Silent (SNP) | VAF 8/24 reads (33%) | catalogued as COSV55595031; called by muse, mutect2, varscan2
- TDRD6 | c.1656T>C p.Y552= | Silent (SNP) | VAF 75/179 reads (42%) | catalogued as rs1219625164; called by muse, mutect2, varscan2
- TENT2 | c.918G>A p.P306= | Silent (SNP) | VAF 68/100 reads (68%) | catalogued as rs768766761, COSV57138984; called by muse, mutect2, varscan2
- ZNF257 | c.1536G>A p.E512= | Silent (SNP) | VAF 19/125 reads (15%) | called by muse, mutect2, varscan2
- ZNF395 | c.123C>T p.A41= | Silent (SNP) | VAF 28/91 reads (31%) | catalogued as rs368064690; called by muse, mutect2, varscan2
- HLA-F | c.-1C>T | 5'UTR (SNP) | VAF 37/110 reads (34%) | catalogued as rs1219869696; called by muse, mutect2, varscan2
- NRP1 | c.1925-2320C>T | Intron (SNP) | VAF 26/171 reads (15%) | called by muse, mutect2, varscan2
- PSME3 | c.406-18A>G | Intron (SNP) | VAF 4/31 reads (13%) | called by muse, mutect2, varscan2
- SSX6P | n.87A>G | RNA (SNP) | VAF 71/117 reads (61%) | called by muse, mutect2, varscan2
